Gene-level copy-number profile of tumor specimen TCGA-06-0182-01A from TCGA case TCGA-06-0182, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.6 years (27,964 days).
Specimen TCGA-06-0182-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.ef08c0b3-e553-4470-9154-2075bbd1b798.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,040 have no estimate.
https://portal.gdc.cancer.gov/files/87f566a7-c701-49ac-9652-1d4262d7e892

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,130; copy number 2: 39,808; copy number 3: 12,641; copy number 5: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-06-0182-01): tumor purity 0.9, ploidy 2.14, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:58,394,596–58,395,138, 1 gene, copy number 5: AC025578.1.
- chr12:67,424,272–67,590,771, 3 genes, copy number 5 (within-gene range 1–5): NTAN1P3, LINC02420, LINC02408.

Autosomal genes at a single copy (total copy number 1): 3,130. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
